Somatic mutation profile of tumor specimen TARGET-30-PASCJJ-01A (aliquot TARGET-30-PASCJJ-01A-01D) from TARGET case TARGET-30-PASCJJ, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.6 years (1,319 days).
Specimen TARGET-30-PASCJJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91962556-2bde-43dc-8aa5-6904a28d3880.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASCJJ-10A (Blood Derived Normal), aliquot TARGET-30-PASCJJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/677a4549-b644-4863-a1ce-3b99967ab4e1

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRWD3 | c.1685G>A p.R562H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV64743373; called by muse, mutect2
- FBN2 | c.3138G>T p.K1046N | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV52489763; called by muse, mutect2, varscan2
- H2BC8 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV55126022; called by muse, mutect2, varscan2
- HOMEZ | c.661C>A p.Q221K | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV62536276; called by muse, mutect2, varscan2
- L1TD1 | c.1134G>T p.E378D | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.191); catalogued as COSV63133021; called by muse, varscan2
- PNLIP | c.997G>T p.G333W | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV65039555; called by muse, mutect2, varscan2
- RMDN1 | c.16C>T p.R6* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as rs1026914855, COSV52203516, COSV52204039; called by muse, mutect2
- RYR3 | c.13531G>A p.A4511T (on ENST00000389232; = p.A4512T on NM_001036.6) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773224069, COSV66776072; called by muse, mutect2, varscan2
- SYTL5 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.917); catalogued as COSV52897982, COSV52905446; called by muse, mutect2, varscan2
- TBC1D26 | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV68608363; called by mutect2, varscan2
- TGM6 | c.1057C>A p.Q353K | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV52477063; called by muse, mutect2, varscan2
- ZNF624 | c.779C>A p.T260N | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV60938405; called by muse, varscan2
- TAP1 | c.1489G>T p.G497W | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ACTR1B | c.726G>T p.T242= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as COSV56703018, COSV56704149; called by muse, mutect2, varscan2
- IGBP1 | c.39C>T p.P13= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV100643018, COSV60555508; called by muse, mutect2
- USP20 | c.118C>T p.L40= | Silent (SNP) | VAF 39/263 reads (15%) | catalogued as COSV59610636; called by muse, mutect2, varscan2
- TREML2 | c.-116C>A | 5'UTR (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
